Somatic mutation profile of tumor specimen 0DRIW8 from CCDI case PBCGPF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.5 years (2,026 days).
Specimen 0DRIW8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03b5431c-c2c8-4231-abb9-49a868375314.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRIWJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21b1e501-4d66-4346-9c35-86b68a060c2f

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, Intron 2, Nonsense Mutation 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKFY1 | c.3197C>T p.S1066L (on ENST00000341657 / NM_001330063.2; = p.S1067L on NM_016376.5) | Missense Mutation (SNP) | VAF 67/612 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs776174515; called by muse, mutect2, varscan2
- CHMP1A | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs773045170, COSV99498210; called by muse, mutect2, varscan2
- DHX16 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 133/693 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs765057075; called by muse, mutect2, varscan2
- DUOX2 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 103/897 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs762753633, COSV66534081, COSV66535400; called by muse, mutect2, varscan2
- HTATIP2 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 36/143 reads (25%) | catalogued as COSV70041119; called by muse, mutect2, varscan2
- NCOR1 | c.5216G>A p.R1739Q | Missense Mutation (SNP) | VAF 57/472 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs772538472; called by muse, mutect2, varscan2
- OR2F2 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 114/828 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1319548320, COSV68833177; called by muse, mutect2
- SLC25A51 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 96/712 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs747952145, COSV54253614; called by muse, mutect2, varscan2
- C16orf78 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- CCDC91 | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JUNB | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- MUC12 | c.2075C>T p.S692F (on ENST00000379442; = p.S549F on NM_001164462.1) | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- POMT2 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 53/327 reads (16%) | called by muse, mutect2, varscan2
- POU1F1 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 87/421 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PTGES3 | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SALL1 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.094); called by muse, mutect2
- SLC25A16 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SLC2A12 | c.1169T>A p.V390E | Missense Mutation (SNP) | VAF 68/430 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC44A5 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 42/508 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ZNF140 | c.1076G>A p.C359Y | Missense Mutation (SNP) | VAF 122/633 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF717 | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 23/455 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.049); called by muse, mutect2
- BLZF1 | c.882G>A p.E294= | Silent (SNP) | VAF 57/361 reads (16%) | called by muse, mutect2, varscan2
- MET | c.2424G>A p.Q808= | Silent (SNP) | VAF 80/630 reads (13%) | called by muse, mutect2, varscan2
- MRPL36 | c.297G>A p.K99= | Silent (SNP) | VAF 110/578 reads (19%) | catalogued as rs760027234; called by muse, mutect2, varscan2
- AL132657.1 | n.258C>T | RNA (SNP) | VAF 69/443 reads (16%) | catalogued as rs983821423, COSV71450910; called by muse, mutect2, varscan2
- GPAT3 | c.854+21G>A | Intron (SNP) | VAF 72/459 reads (16%) | called by muse, mutect2, varscan2
- IZUMO4 | c.537-88C>T | Intron (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- SNX13 | c.-99G>T | 5'UTR (SNP) | VAF 7/77 reads (9%) | catalogued as rs1188284318; called by muse, mutect2, varscan2
